Gene-level copy-number profile of tumor specimen REBC-AC8N-TTP1-A from REBC case REBC-AC8N, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: female; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-AC8N-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f77187aa-4142-4f6d-b134-76e36baa1102.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-AC8N-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/05b484e9-7dc4-4dba-8eb3-4a8057eca081

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 423; copy number 2: 57,626; copy number 3: 317; copy number 4: 27; copy number 5: 8.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,315,040–2,405,442, 6 genes, copy number 5 (within-gene range 2–5): AL590822.3, MORN1, AL589739.1, AL513477.1, AL513477.2, RER1.
- chr2:197,569–266,398, 2 genes, copy number 5 (within-gene range 2–5): AC079779.1, SH3YL1.

Autosomal genes at a single copy (total copy number 1): 423. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
